Surgical pathology report (de-identified scan), TCGA case TCGA-VS-AA62, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-AA62-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD O-3
Carcinoma, squamous cell NOS
807013
Site: Cervix NOS
C53.9
JW 3/20/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of cervix":

Moderately differentiated squamous cell carcinoma, invasive.

Source: NCI Genomic Data Commons file 912ed559-d4f1-4d3a-b999-c711e232f47c (TCGA-VS-AA62.33FDBF1D-90D6-4D05-9AC9-9983421A4CAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).